Somatic mutation profile of tumor specimen TCGA-GC-A3BM-01A (aliquot TCGA-GC-A3BM-01A-11D-A22Z-08) from TCGA case TCGA-GC-A3BM, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 70.1 years (25,609 days).
Specimen TCGA-GC-A3BM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3dfd9a60-ae42-45cb-b884-a33bacfb2fb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GC-A3BM-10A (Blood Derived Normal), aliquot TCGA-GC-A3BM-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77b926d5-9bcc-4553-996b-46d76faa8a71

The open-access MAF lists 140 somatic variants for this specimen: 98 protein-altering or splice-affecting, 38 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 38, Frame Shift Del 7, Nonsense Mutation 3, Splice Region 2, 5'UTR 2, Frame Shift Ins 1, 3'Flank 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 29/44 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSL1 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as rs200424498, COSV55664168; called by muse, mutect2, varscan2
- ADRA1A | c.1155C>A p.F385L | Missense Mutation (SNP) | VAF 109/236 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV52368676; called by muse, mutect2, varscan2
- AGRN | c.4381C>T p.R1461W | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65069746; called by muse, mutect2, varscan2
- ALKBH5 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 47/51 reads (92%) | SIFT tolerated (0.66); PolyPhen benign (0.054); catalogued as COSV52760102; called by muse, mutect2, varscan2
- ANKRD28 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 56/62 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67518977; called by muse, mutect2, varscan2
- ANKRD36 | c.176A>G p.N59S | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs753908837, COSV70741244; called by muse, mutect2, varscan2
- ARHGAP35 | c.1872del p.D624Efs*4 | Frame Shift Del (DEL) | VAF 108/270 reads (40%) | catalogued as COSV68333033; called by mutect2, pindel, varscan2
- ARHGEF5 | c.4724G>A p.R1575H | Missense Mutation (SNP) | VAF 92/203 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs200654855; called by muse, mutect2, varscan2
- ATP10A | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as rs1235667001, COSV63519927; called by muse, mutect2, varscan2
- ATP10A | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV63521526; called by mutect2, varscan2
- BRSK1 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs753486933, COSV58665688; called by muse, mutect2, varscan2
- C10orf82 | c.374G>C p.R125T | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100980095, COSV65024715; called by muse, mutect2, varscan2
- C3orf56 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV67756349; called by muse, mutect2, varscan2
- CACNA1A | c.2815C>T p.R939W | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs931394162, COSV64203169; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAVIN1 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63812258, COSV63812843; called by muse, mutect2, varscan2
- CHD7 | c.2278A>G p.T760A | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as rs1237122943, COSV71112471; called by muse, mutect2, varscan2
- CLEC18B | c.753T>G p.C251W | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100375888; called by muse, mutect2, varscan2
- CNTNAP2 | c.2744G>A p.R915H | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.617); catalogued as rs369919189, COSV62155012; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A2 | c.4951C>T p.R1651C | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569071842, COSV64628491; called by muse, mutect2, varscan2
- DBT | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs199954954, COSV100923452; called by muse, mutect2
- DNAH5 | c.10612T>G p.F3538V | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54237140; called by muse, mutect2, varscan2
- FAM171B | c.1281A>T p.L427F | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as rs1240837901, COSV59005523; called by muse, mutect2, varscan2
- FBXO34 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 93/180 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58255443; called by muse, mutect2, varscan2
- FRAS1 | c.1375T>C p.Y459H | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1159801103, COSV53625109; called by muse, mutect2, varscan2
- GABRA5 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV59482229; called by muse, mutect2, varscan2
- GIN1 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV67537287; called by muse, mutect2, varscan2
- GPR142 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1340847032, COSV59519526; called by muse, mutect2, varscan2
- GPR179 | c.1219C>T p.R407C (on ENST00000621958; = p.R406C on NM_001004334.4) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs373472248; called by muse, mutect2, varscan2
- HTR2C | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 201/217 reads (93%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as rs782421726, COSV52217490; called by muse, mutect2, varscan2
- IGKV1-6 | c.215C>G p.A72G | Missense Mutation (SNP) | VAF 119/259 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs755128338; called by muse, mutect2, varscan2
- INPPL1 | c.3571G>T p.G1191W | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV53357156, COSV53360076; called by muse, mutect2, varscan2
- KANK1 | c.3246-2A>G p.X1082_splice | Splice Site (SNP) | VAF 39/72 reads (54%) | catalogued as COSV63213613; called by muse, mutect2, varscan2
- KIF5A | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54056246; called by muse, mutect2, varscan2
- KPNA5 | c.999G>A p.Q333= | Splice Region (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100706169, COSV62653260; called by muse, mutect2, varscan2
- LAMA5 | c.1755G>A p.Q585= | Splice Region (SNP) | VAF 19/42 reads (45%) | catalogued as rs781640497, COSV53364313; called by muse, mutect2, varscan2
- LMBRD1 | c.672G>C p.L224F (on ENST00000649011; = p.L202F on NM_018368.4) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV65298151; called by muse, mutect2, varscan2
- LPO | c.104C>G p.S35C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV51856618, COSV51860333; called by muse, mutect2, varscan2
- LPO | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1312023104, COSV51860346; called by muse, mutect2, varscan2
- LRRC41 | c.1666C>T p.R556C | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV58440820; called by muse, mutect2, varscan2
- LRRC7 | c.2788G>A p.V930I (on ENST00000651989 / NM_001370785.2; = p.V897I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.011); catalogued as rs758138383, COSV50503978; called by muse, mutect2, varscan2
- MASTL | c.1793C>G p.S598C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV60911489; called by muse, mutect2, varscan2
- MCRS1 | c.612G>C p.Q204H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as COSV59460401; called by muse, mutect2, varscan2
- MRTFB | c.1205A>T p.D402V | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57959244; called by muse, mutect2, varscan2
- MS4A12 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs767901392, COSV50014933, COSV99189769; called by muse, mutect2, varscan2
- MST1R | c.3782C>T p.T1261I | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs757524599, COSV56570717; called by muse, mutect2, varscan2
- MTTP | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs749466528, COSV55507547; called by muse, mutect2, varscan2
- MXRA8 | c.338C>G p.S113W | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58511074; called by muse, mutect2, varscan2
- MYF5 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 47/66 reads (71%) | catalogued as COSV57356767; called by muse, mutect2, varscan2
- MYO7B | c.3610G>A p.A1204T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV67349144; called by muse, mutect2, varscan2
- OBSCN | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV52736144; called by muse, mutect2, varscan2
- P4HA3 | c.690G>C p.L230F | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59042617; called by muse, mutect2, varscan2
- PCDHA5 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV65354060; called by muse, mutect2
- PLEKHA7 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 51/56 reads (91%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as rs1407713427, COSV63048117; called by muse, mutect2, varscan2
- PRTN3 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.157); catalogued as rs748173148; called by muse, mutect2
- RASAL2 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as rs564071894, COSV62717213; called by muse, mutect2, varscan2
- RET | c.3241G>C p.D1081H | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as COSV60700237; called by muse, mutect2, varscan2
- RIPK4 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60188365; called by muse, mutect2, varscan2
- RTL3 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.89); PolyPhen benign (0.035); catalogued as COSV58184765; called by muse, mutect2, varscan2
- RYR2 | c.4279T>A p.Y1427N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV63696223; called by muse, mutect2, varscan2
- SACS | c.9551G>A p.R3184H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as rs200453385, COSV66543128; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCNM1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV54860178; called by muse, mutect2, varscan2
- SF3B1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV59219540; called by muse, mutect2, varscan2
- SIRT5 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.679); catalogued as rs765381829, COSV63080219; called by muse, mutect2, varscan2
- SLC24A2 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 50/66 reads (76%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53868785, COSV53873444; called by muse, mutect2, varscan2
- SNAP29 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.025); catalogued as COSV53143342; called by muse, mutect2, varscan2
- SORCS3 | c.1556A>T p.N519I | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63815704; called by muse, mutect2, varscan2
- SPTA1 | c.6632G>A p.R2211H | Missense Mutation (SNP) | VAF 109/199 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs751062593, COSV63749330; called by muse, mutect2, varscan2
- TBC1D1 | c.1869G>C p.M623I | Missense Mutation (SNP) | VAF 136/195 reads (70%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV54722412; called by muse, mutect2, varscan2
- TMCC2 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as rs1445166472, COSV58004733; called by muse, mutect2, varscan2
- TMEM266 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as COSV66380147; called by muse, mutect2, varscan2
- TRAV21 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs144813465; called by muse, mutect2, varscan2
- TRIM25 | c.1781C>A p.A594D | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV57544779; called by muse, mutect2, varscan2
- TRMT10B | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.549); catalogued as COSV53050726; called by muse, mutect2, varscan2
- TRPV4 | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 64/94 reads (68%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV55683364; called by muse, mutect2, varscan2
- TTN | c.25451C>T p.P8484L (on ENST00000591111; = p.P7557L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/106 reads (68%) | PolyPhen benign (0); catalogued as rs778967914, COSV60019294; called by muse, mutect2
- UBR5 | c.4571C>T p.S1524L | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.175); catalogued as COSV55292477; called by muse, mutect2, varscan2
- VCP | c.1285C>T p.L429F | Missense Mutation (SNP) | VAF 141/276 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.257); catalogued as COSV62721226; called by muse, mutect2, varscan2
- VDAC1 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.906); catalogued as rs769081892, COSV54737815; called by muse, mutect2, varscan2
- XIRP2 | c.6529G>A p.D2177N (on ENST00000628543; = p.D2352N on NM_152381.6) | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.444); catalogued as COSV54713699, COSV99737875; called by muse, mutect2, varscan2
- XPA | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.025); catalogued as rs771752416, COSV64305365; called by muse, mutect2, varscan2
- XPO5 | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as rs375072367; called by muse, mutect2, varscan2
- ZNF649 | c.952C>G p.H318D | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV56816816; called by muse, mutect2, varscan2
- ZNF792 | c.61A>G p.I21V | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV68693760; called by muse, mutect2, varscan2
- CDKN2A | c.265_266del p.G89Lfs*30 | Frame Shift Del (DEL) | VAF 16/20 reads (80%) | called by mutect2, pindel, varscan2
- DEF6 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- EP300 | c.1142_1143del p.H381Lfs*29 | Frame Shift Del (DEL) | VAF 46/128 reads (36%) | called by pindel, varscan2
- ERCC6 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- GPR137C | c.1253_1256del p.N418Ifs*7 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- KMT2C | c.13927_13936del p.C4643Kfs*13 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | called by mutect2, pindel, varscan2
- KMT2D | c.7854_7887del p.P2619Mfs*61 | Frame Shift Del (DEL) | VAF 35/53 reads (66%) | called by mutect2, pindel
- KNDC1 | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2
- LRRC8B | c.2199del p.N735Ifs*3 | Frame Shift Del (DEL) | VAF 43/121 reads (36%) | called by mutect2, pindel, varscan2
- NKX6-3 | c.583C>T p.R195W (on ENST00000518699 / NM_001364841.2; = p.R65W on NM_152568.3) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOP14 | c.866dup p.E290Gfs*3 | Frame Shift Ins (INS) | VAF 21/106 reads (20%) | called by mutect2, pindel, varscan2
- PABPC3 | c.1439C>G p.S480* | Nonsense Mutation (SNP) | VAF 33/102 reads (32%) | called by muse, mutect2, varscan2
- PRAMEF15 | c.537A>C p.L179F | Missense Mutation (SNP) | VAF 72/797 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, varscan2
- TRAV39 | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- ALX4 | c.720C>T p.D240= | Silent (SNP) | VAF 109/122 reads (89%) | catalogued as rs766990322, COSV61327388; called by muse, mutect2, varscan2
- ATF6 | c.1044G>A p.L348= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV63406737; called by muse, mutect2, varscan2
- BUD13 | c.792C>T p.L264= | Silent (SNP) | VAF 144/158 reads (91%) | catalogued as rs753560863, COSV52769110; called by muse, mutect2, varscan2
- CDK5RAP3 | c.720G>A p.E240= | Silent (SNP) | VAF 49/141 reads (35%) | catalogued as rs374509909; called by muse, varscan2
- COL22A1 | c.4470G>A p.A1490= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs748451665, COSV57341187; called by muse, mutect2, varscan2
- DCT | c.1371C>T p.I457= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1223647833; called by muse, mutect2
- FAT3 | c.5745C>T p.P1915= | Silent (SNP) | VAF 24/27 reads (89%) | catalogued as COSV53137482; called by muse, mutect2, varscan2
- FCRL2 | c.357C>T p.I119= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as COSV63834165; called by muse, mutect2, varscan2
- FGG | c.1098C>T p.H366= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs374166238, COSV100271639; called by muse, mutect2, varscan2
- GFPT1 | c.984G>A p.Q328= (on ENST00000357308 / NM_001244710.2; = p.Q310= on NM_002056.4) | Silent (SNP) | VAF 87/164 reads (53%) | catalogued as COSV61948982; called by muse, mutect2, varscan2
- GRIN2B | c.3456C>T p.T1152= | Silent (SNP) | VAF 67/102 reads (66%) | catalogued as rs752200554, COSV74206675, COSV74206895; called by muse, mutect2, varscan2
- HPN | c.768C>T p.N256= | Silent (SNP) | VAF 21/135 reads (16%) | catalogued as rs1014770632, COSV52882962; called by muse, mutect2, varscan2
- HS6ST3 | c.60C>G p.V20= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV65013157; called by muse, mutect2, varscan2
- KCNAB2 | c.1038C>T p.S346= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV51237642; called by muse, mutect2
- LPIN1 | c.405G>A p.T135= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs1373294657, COSV56764132; called by muse, mutect2, varscan2
- LY9 | c.294T>A p.I98= | Silent (SNP) | VAF 75/168 reads (45%) | catalogued as COSV54435566; called by muse, mutect2, varscan2
- MARK4 | c.1011G>A p.V337= | Silent (SNP) | VAF 126/290 reads (43%) | catalogued as COSV53465739; called by muse, mutect2, varscan2
- MBD4 | c.1737A>G p.L579= | Silent (SNP) | VAF 137/146 reads (94%) | catalogued as rs1157788131, COSV51445079; called by muse, mutect2, varscan2
- MDN1 | c.7524C>T p.Y2508= | Silent (SNP) | VAF 98/221 reads (44%) | catalogued as COSV65524558; called by muse, mutect2, varscan2
- MEGF6 | c.2668C>T p.L890= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- MST1R | c.3288C>T p.V1096= | Silent (SNP) | VAF 137/149 reads (92%) | catalogued as rs776345521, COSV56570767; called by muse, mutect2, varscan2
- MUC16 | c.10656T>A p.T3552= | Silent (SNP) | VAF 92/230 reads (40%) | catalogued as COSV67477732; called by muse, mutect2, varscan2
- MYH1 | c.5379G>A p.T1793= | Silent (SNP) | VAF 123/135 reads (91%) | catalogued as rs547325713, COSV56852022; called by muse, mutect2, varscan2
- NLN | c.2019G>A p.G673= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV66766396; called by muse, mutect2, varscan2
- OR2T8 | c.165G>A p.T55= | Silent (SNP) | VAF 70/186 reads (38%) | catalogued as rs562352417, COSV60662094, COSV60664997; called by muse, varscan2
- OR6S1 | c.870A>G p.P290= | Silent (SNP) | VAF 78/177 reads (44%) | catalogued as COSV57838645; called by muse, mutect2, varscan2
- PABPC5 | c.1059G>A p.E353= | Silent (SNP) | VAF 29/31 reads (94%) | catalogued as rs759967355, COSV57039684, COSV57041794; called by muse, mutect2, varscan2
- PATL1 | c.1758G>A p.Q586= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV55690926; called by muse, mutect2, varscan2
- PCBP3 | c.771C>G p.L257= | Silent (SNP) | VAF 63/178 reads (35%) | catalogued as COSV68408625, COSV68408831; called by muse, mutect2, varscan2
- PPME1 | c.975A>G p.R325= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV60297223; called by muse, mutect2, varscan2
- PTPRS | c.4722C>T p.V1574= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV53626462; called by muse, mutect2, varscan2
- RTL9 | c.3348A>G p.G1116= | Silent (SNP) | VAF 117/124 reads (94%) | catalogued as rs1244632068, COSV71825877; called by muse, mutect2, varscan2
- SERINC3 | c.66A>G p.S22= | Silent (SNP) | VAF 86/138 reads (62%) | catalogued as rs1426273051, COSV54857579; called by muse, mutect2, varscan2
- SLC9A5 | c.624C>T p.G208= | Silent (SNP) | VAF 71/152 reads (47%) | catalogued as rs780350480, COSV55361987; called by muse, mutect2, varscan2
- SOWAHA | c.1293G>A p.S431= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs753498449, COSV101097651; called by muse, varscan2
- TIMM50 | c.81G>A p.A27= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV58679742; called by muse, mutect2, varscan2
- TTLL7 | c.1042C>T p.L348= | Silent (SNP) | VAF 67/140 reads (48%) | catalogued as rs1351176259, COSV53086151; called by muse, mutect2, varscan2
- ZNF257 | c.1491C>T p.N497= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs374023957, COSV71306568; called by muse, mutect2, varscan2
- AP3D1 | c.-1G>C | 5'UTR (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100642615, COSV100642898; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445924 C>T | 3'Flank (SNP) | VAF 70/165 reads (42%) | catalogued as rs780437457; called by muse, mutect2, varscan2
- KCNK7 | c.718+42_718+43del | Intron (DEL) | VAF 32/108 reads (30%) | called by pindel, varscan2
- NDUFA7 | c.-1G>C | 5'UTR (SNP) | VAF 9/19 reads (47%) | catalogued as COSV100035514; called by muse, mutect2, varscan2
